Somatic mutation profile of tumor specimen MP2PRT-PASXRL-TMP1-A (aliquot MP2PRT-PASXRL-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PASXRL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.1 years (2,213 days).
Specimen MP2PRT-PASXRL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce762093-f8a8-43ab-a108-53362a98c5a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASXRL-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASXRL-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ebfe03b-c87a-4049-a5ee-f299209e3db4

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LMOD3 | c.506C>T p.T169M | Missense Mutation (SNP) | VAF 90/420 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.151); catalogued as rs181564355; ClinVar: uncertain significance; called by muse, varscan2
- PPP1R32 | c.527C>T p.T176M | Missense Mutation (SNP) | VAF 66/324 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs770730184, COSV100087767; called by muse, varscan2
- CFAP69 | c.2041A>G p.K681E | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- DST | c.20096A>T p.K6699I (on ENST00000361203 / NM_001374722.1; = p.K4396I on NM_015548.5) | Missense Mutation (SNP) | VAF 46/291 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PPIL3 | c.43G>C p.E15Q | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- STXBP2 | c.1523C>T p.S508F | Missense Mutation (SNP) | VAF 46/442 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- TMEM176A | c.484C>G p.P162A | Missense Mutation (SNP) | VAF 44/302 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRNT1 | c.866C>T p.S289L | Missense Mutation (SNP) | VAF 25/238 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- UBA2 | c.1110G>A p.M370I | Missense Mutation (SNP) | VAF 15/190 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.445); called by muse, mutect2
- C15orf40 | c.12C>T p.L4= | Silent (SNP) | VAF 112/283 reads (40%) | catalogued as rs997454474, COSV55602032; called by muse, mutect2, varscan2
- KLHL32 | c.258C>T p.H86= | Silent (SNP) | VAF 34/146 reads (23%) | catalogued as rs531719235, COSV65114989; called by muse, mutect2, varscan2
- NXN | c.678C>G p.G226= | Silent (SNP) | VAF 149/309 reads (48%) | catalogued as rs936914898; called by muse, mutect2, varscan2
- SLC4A5 | c.3177C>T p.F1059= | Silent (SNP) | VAF 35/252 reads (14%) | catalogued as COSV61035040; called by muse, varscan2
- IGHV1-58 | chr14:106627248 ins TC | 5'Flank (INS) | VAF 50/102 reads (49%) | called by mutect2*, pindel, varscan2*
